CCDI case PBBZBS — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Connective, subcutaneous and other soft tissues.
https://portal.gdc.cancer.gov/cases/b4a150cc-2351-4627-bdef-84f8e96b559a

Demographics
Sex at birth: male; Race: white; Vital status: Alive.

Diagnoses (1)
1. Desmoplastic fibroma: ICD-O-3 morphology code: 8823/0; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of upper limb and shoulder; Age at diagnosis: 23.3 years (8,528 days).

Biospecimens (3 samples)
- Sample 0DL6RL: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DL6RU: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DL6SF: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
